Surgical pathology report (de-identified scan), TCGA case TCGA-EY-A2OO, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site University of North Carolina, specimen TCGA-EY-A2OO-01A (Primary Tumor).

[page 1 of 5]
PATHOLOGY REVISED REPORT

100-0-3

adenocarcinoma, endometrioid (8380/3)
and serous (8441/3) - Code to highest
Site: Endometrium C54.1 8441/3
8/24/11 lw

Amendments:

Amended: by

Reason: Changes in diagnosis

Comment: Current pathologic stage using new criteria. pT1b to pT1a and FIGO stage grouping IB to IA.

Previous Signout Date:

Diagnosis:

A: Uterus and cervix, radical hysterectomy and bilateral salpingo-oophorectomy:

Location of tumor: Endometrium

Histologic type: Adenocarcinoma, mixed endometrioid (90%) and serous (10%) (A3, A4)

Histologic grade (FIGO): 3 (architectural grade 2-3, nuclear grade 3)

Extent of invasion: into the myometrium

Myometrial invasion: Superficial myometrial invasion is present
Depth: 1 mm Wall thickness: 7 mm Percent: 14% (A3)

Serosal involvement: not identified

Lower uterine segment involvement: not identified

Cervical involvement: not identified

Adnexal involvement (see below): not identified

Other sites: N/A

Cervical/vaginal margin and distance: widely negative

Lymphovascular Space Invasion: present (A6)

Regional lymph nodes (see other specimens):

Total number involved: 0

Total number examined: 24

Other Pathologic findings:

HPV Discrepancy		X
Disagreement: Primary noted		X
Case is (check)		
Reviewed Initially		
Reviewed		

CMIS 8/24/11

[page 2 of 5]
- Myometrium shows leiomyomas with hyalinization and adenomyosis
- Uninvolved endometrium shows atrophic endometrium
- Cervix shows chronic cervicitis

Hormone receptor status: Tumor is estrogen receptor (ER) negative (1+, <1%) and progesterone receptor (PR) negative (0), by immunohistochemistry, with appropriately staining positive and negative internal and external controls

AJCC Pathologic stage: pT1A pN0 pMx

FIGO Stage grouping: IA (based on updated 2008 FIGO staging criteria)

These stages are based on information available at the time of this report, and are subject to change pending additional information and clinical review

Ovary, right, oophorectomy:

- Endometriosis
- Serous inclusion glands
- Negative for atypia and malignancy

Ovary, left, oophorectomy:

- Endometriosis
- Serous inclusion glands
- Negative for atypia and malignancy

Fallopian tube, right, salpingectomy:

- Negative for malignancy

Fallopian tube, left, salpingectomy:

- Negative for malignancy

B: Lymph node, right peri-aortic, removal

- No evidence of malignancy in two lymph nodes (0/2)

C: Lymph node, left peri-aortic, removal

- No evidence of malignancy in one lymph node (0/1)

D: Lymph node, right pelvic, removal

- No evidence of malignancy in eleven lymph nodes (0/11)

[page 3 of 5]
E: Lymph node, left pelvic, removal
- No evidence of malignancy in ten lymph nodes (0/10)

Clinical History:

year-old female with endometrial cancer.

Gross Description:

Received are five appropriately labeled containers.

Container A:

Adnexa: bilateral adnexa received attached to the specimen

Weight: 136 grams

Shape: distorted but roughly pear shaped

Dimensions:

height: 11.3 cm

anterior to posterior width: 4.5 cm

breadth at fundus: 7 cm

Serosa: smooth, purple/red and glistening

Cervix:

length of endocervical canal: 2.3 cm

ectocervix: white/pink, smooth and glistening

endocervix: trabecular, yellow and glistening

Endomyometrium:

length of endometrial cavity: 3.6 cm

width of endometrial cavity at fundus: 2.0 cm

tumor findings:

dimensions: 2.2 x 1.3 x 0.2 cm

appearance: granular, slightly exophytic

location and extent: The tumor is located on the left anterior wall near the cornu.

myometrial invasion: no apparent invasion

thickness of myometrial wall at deepest gross invasion: 1.5 cm

other findings or comments: The myometrium also contains multiple intramural and subserosal firm white circumscribed nodules measuring up to 3.6 cm in greatest dimension having a homogeneous white whorled cut surfaces.

Adnexa:

Right ovary:

dimensions: 3.4 x 1.4 x 1.2 cm

external surface: smooth, glistening tan/pink

cut surface: grossly unremarkable

Right fallopian tube:

dimensions: 6.5 x 0.5 cm

[page 4 of 5]
other findings: There is a patent lumen on sectioning and the tube is markedly cauterized near the cornu.

Left ovary:

dimensions: 3.5 x 1.8 x 1.2 cm

external surface: smooth, glistening, tan/pink

cut surface: grossly unremarkable with a few thin walled clear fluid-filled cysts

Left fallopian tube:

dimensions: 5.8 x 0.5 cm

other findings: There is a patent lumen on sectioning and there is abundant cautery artifact near the cornu.

Lymph nodes: submitted separately

Other comments: none

Digital photograph taken: not taken

Tissue submitted for special investigations: Fibroid tissue is given to Tissue Procurement.

Block Summary:

- A1 - anterior cervix
- A2 - anterior lower uterine segment
- A3 - anterior mid corpus
- A4 - anterior upper corpus/fundus
- A5 - posterior cervix
- A6 - posterior lower uterine segment
- A7 - posterior mid corpus
- A8 - posterior upper corpus/fundus
- A9 - right ovary and right fallopian tube
- A10 - left ovary and left fallopian tube
- A11, A12 - representative sections from fibroid nodules

Container B is additionally labeled "right peri-aortic node." It holds a 3.2 x 2.6 x 0.5 cm aggregate of cauterized yellow/tan fibrofatty tissue containing one lymph node candidate. The lymph node candidate is submitted in block B1. The remainder of the fat is submitted in block B2, NTR.

Container C is additionally labeled "left peri-aortic node." It holds a 2.3 x 1.5 x 0.3 cm aggregate of cauterized yellow/tan fatty tissue; block C1, NTR.

Container D is additionally labeled "right pelvic nodes." It

[page 5 of 5]
holds a 6.4 x 2.5 x 1.2 cm aggregate of markedly cauterized yellow/tan fibrofatty tissue. Also lymph node candidates measuring up to 3.6 cm in greatest dimension are identified.

Block Summary:

- D1 - five lymph node candidates
- D2 - three lymph node candidates
- D3 - two lymph node candidates
- D4 - one lymph node candidate, bisected
- D5-D6 - one lymph node candidate, sectioned
- D7-D8 - remainder of fat, NTR

Container E is additionally labeled "left pelvic nodes." It holds a 4.5 x 3.2 x 1.0 cm aggregate of markedly cauterized yellow/tan fibrofatty tissue which is dissected for lymph node candidates. Lymph node candidates measuring up to 3.7 cm in greatest dimension are identified.

Block summary:

- E1 - five lymph node candidates
- E2 - three lymph node candidates
- E3 - one lymph node candidate, bisected
- E4 - one lymph node candidate, bisected
- E5-E6 - remainder of fat, NTR

Source: NCI Genomic Data Commons file 03eea047-af95-440b-b8a5-a4834c4fe312 (TCGA-EY-A2OO.CC94C4BA-FBF6-4F0D-93DD-C2D98D965DF8.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).